Gene-level copy-number profile of tumor specimen MP2PRT-PARUBU-TMP1-A from MP2PRT case MP2PRT-PARUBU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,134 days).
Specimen MP2PRT-PARUBU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cb722c95-9656-49bf-aa12-bf7ddfdb133d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARUBU-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/55ebc1f8-6fdf-43c4-a7e2-d31b6f04804c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 120; copy number 1: 3,299; copy number 2: 55,408; copy number 3: 65.

Homozygous deletions (total copy number 0; autosomes only): 120 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,254,015, 37 genes (within-gene range 0–2): MALLP2, MIR4436A, IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr7:38,256,337–38,311,808, 9 genes (within-gene range 0–1): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:105,881,034–106,001,824, 34 genes (within-gene range 0–1): IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1.
- chr14:106,531,141–106,715,181, 36 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48, IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,034. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
